Gene-level copy-number profile of tumor specimen TCGA-N8-A4PQ-01A from TCGA case TCGA-N8-A4PQ, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Age at diagnosis: 76.0 years (27,772 days).
Specimen TCGA-N8-A4PQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.a5827926-87d2-41a4-90d9-2863d075ada4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A4PQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a7530b2-f153-4416-851f-9883b785c983

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,142; copy number 3: 19,799; copy number 4: 18,904; copy number 5: 8,414; copy number 6: 2,655; copy number 7: 273; copy number 8: 83; copy number 9: 500; copy number 10: 937; copy number 11: 6; copy number 13: 94; copy number 16: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A4PQ-01A-11D-A28Q-01): tumor purity 0.64, ploidy 3.9, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,897 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,688,749–54,537,758, 29 genes, copy number 7: RNU7-95P, NDC1, AL049745.1, AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1, AL035415.1, AC099796.2, LINC02784, AC099796.1, HNRNPA1P63.
- chr3:13,650,696–13,937,477, 4 genes, copy number 8: LINC00620, WNT7A, VN1R20P, FGD5P1.
- chr5:139,684,645–141,012,347, 71 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9–16 (broad region; genes not listed).
- chr10:68,827,531–69,964,275, 35 genes, copy number 7 (within-gene range 5–7): STOX1, RNU6-697P, AL359844.1, DDX50, RNU6-571P, DDX21, KIFBP, MED28P1, ACTBP14, SRGN, Metazoa_SRP, VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26, COL13A1.
- chr10:100,735,603–101,137,789, 17 genes, copy number 7: PAX2, Y_RNA, AL138762.1, SLF2, AL133215.3, MRPL43, SEMA4G, MIR608, AL133215.1, TWNK, LZTS2, PDZD7, SFXN3, AL133215.2, KAZALD1, TLX1NB, TLX1.
- chr11:8,391,868–8,682,694, 4 genes, copy number 8 (within-gene range 4–8): STK33, AP006442.1, TRIM66, AC091053.2.
- chr11:8,684,227–8,685,569, 2 genes, copy number 8: SNORA3A, SNORA3B.
- chr12:122,167,738–122,203,471, 1 gene, copy number 7 (within-gene range 4–7): LRRC43.
- chr12:122,203,681–123,441,852, 48 genes, copy number 7: B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A, CLIP1, RPL21P1, CLIP1-AS1, ZCCHC8, AC127002.1, AC127002.2, RSRC2, KNTC1, AC026333.1, AC026333.4, AC026333.3, HCAR2, HCAR3, HCAR1, AC026333.2, DENR, Y_RNA, CCDC62, HIP1R, VPS37B, AC027290.1, AC027290.2, ABCB9, OGFOD2, AC026362.1, ARL6IP4, PITPNM2, MIR4304, PITPNM2-AS1, AC026362.2, MPHOSPH9, AC073857.1, C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2.
- chr17:39,671,122–40,136,917, 24 genes, copy number 7–8 (within-gene range 3–8): PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1.
- chr17:47,891,229–48,968,596, 70 genes, copy number 8 (broad region; genes not listed).
- chr17:64,145,970–64,413,776, 7 genes, copy number 10: SNHG25, SNORD104, AC025362.1, SNORA50C, TEX2, RPL31P57, PECAM1.
- chr22:31,388,733–32,464,484, 51 genes, copy number 7 (within-gene range 5–7): RNU6-338P, DRG1, EIF4ENIF1, AL096701.3, RNU6-28P, SFI1, AL096701.4, H2AZP6, AL096701.2, AL096701.1, PISD, MIR7109, PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1, AL008723.3, RFPL2, IGLCOR22-1, SLC5A4-AS1, SLC5A4, CPSF1P1, AL008723.2, AL021937.3, RFPL3, IGLCOR22-2, RFPL3S, AL021937.6, AL021937.5, AL021937.1, IGLVIVOR22-2, AL021937.4, AL021937.2, RTCB, BPIFC.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
